Gene-level copy-number profile of tumor specimen TCGA-BR-6454-01A from TCGA case TCGA-BR-6454, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 58.9 years (21,501 days).
Specimen TCGA-BR-6454-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.18ffcebe-7796-42c5-9121-b34de5cd68dc.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BR-6454-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1e001559-340a-48d9-8a75-d9afaf1ec590

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 1,357; copy number 2: 26,873; copy number 3: 18,631; copy number 4: 10,139; copy number 5: 208; copy number 6: 722; copy number 7: 567; copy number 8: 578; copy number 9: 101; copy number 10: 388; copy number 11: 185; copy number 14: 39; copy number 20: 29.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BR-6454-01A-11D-1799-01): tumor purity 0.37, ploidy 2.67, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,616,822–60,618,079, 2 genes: AC104164.2, MIR548BB.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,817 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:211,571,568–211,853,703, 12 genes, copy number 11 (within-gene range 4–11): SLC30A1, AC105275.2, AL356310.1, LINC01693, NEK2, FDPSP8, AC096637.2, AC096637.1, LPGAT1, RN7SL344P, Y_RNA, LPGAT1-AS1.
- chr7:91,638,847–100,797,797, 241 genes, copy number 11–20 (broad region; genes not listed).
- chr11:66,638,667–70,436,584, 147 genes, copy number 6 (broad region; genes not listed).
- chr14:49,693,105–49,753,150, 1 gene, copy number 9 (within-gene range 4–9): KLHDC1.
- chr14:49,768,130–53,157,528, 100 genes, copy number 9 (broad region; genes not listed).
- chr14:105,398,538–106,875,071, 208 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr15:71,822,291–72,118,577, 1 gene, copy number 6 (within-gene range 4–6): MYO9A.
- chr15:71,972,206–101,933,350, 812 genes, copy number 6–7 (broad region; genes not listed).
- chr19:27,681,072–41,930,150, 568 genes, copy number 6–8 (within-gene range 2–8) (broad region; genes not listed).
- chr20:35,433,029–64,313,132, 727 genes, copy number 6–10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,322. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
